Surgical pathology report (de-identified scan), TCGA case TCGA-19-2629, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Case Western, specimen TCGA-19-2629-01A (Primary Tumor).

TCGA-19-2629

2629

SURGICAL PATHOLOGY REPORT**FINAL DIAGNOSIS**

A, B. RIGHT PARIETAL LOBE OF BRAIN, LESION, BIOPSY AND PARTIAL REMOVAL:
-- GLIOBLASTOMA MULTIFORME (WHO GRADE IV).

Note: CD3 immunostaining labels small reactive-appearing lymphocytes. CD20 staining is negative.

One or more of the reagents used to perform assays on this specimen MAY have contained components considered to be analyte specific reagents [REDACTED] have not been cleared or approved by the U.S. Food and Drug Administration. These assays were developed and their performance characteristics determined by [REDACTED]. The assays were performed with appropriate positive and negative controls.

Electronically Signed Out By [REDACTED]

By the signature on this report, the individual or group listed as making the Final Interpretation/Diagnosis certifies that they have reviewed this case.

Intraoperative Consult Diagnosis

A. GLIOBLASTOMA MULTIFORME.

Senior pathologist: [REDACTED]

Clinical History:

right parietal brain lesion

Specimens Submitted As:

A: RIGHT PARIETAL BRAIN LESION

B: RIGHT PARIETAL BRAIN LESION

Gross Description:

A. Received fresh labeled with the patient's name, hospital number and "right parietal brain lesion" are 5 tan-pink soft tissue fragments, 2 x 1 x 0.4 cm in aggregate. A touch prep is performed. A portion of specimen is submitted for intraoperative consultation. The entire specimen is submitted in two cassettes.

B: Received fresh, post fixed in formalin, labeled with the patient's name and number, are multiple irregular, opaque white to pink-tan to red-brown, soft cerebriform tissue fragments measuring in aggregate 5.0 x 2.8 x 1.0 cm. Submitted entirely in three cassettes.

Source: NCI Genomic Data Commons file 4c514528-f4f0-47b5-af8e-f4bff0458bd9 (TCGA-19-2629.974B6590-7B55-4D77-94E0-F5C48204FDD7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).